Somatic mutation profile of tumor specimen MBCProject_4634_T2_WES (aliquot MBCProject_4634_T2_WES_1) from CMI case MBCProject_4634, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.2 years (12,859 days).
Specimen MBCProject_4634_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d2a88d1-70ea-4d81-bb17-38aab767bdb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4634_SALIVA (Saliva), aliquot MBCProject_4634_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bc9513e-2235-43b8-85f3-f5a8ae44ccc3

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Intron 4, Frame Shift Del 3, In Frame Del 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.2329C>G p.R777G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100584157; called by muse, mutect2, varscan2
- ASCL1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1245236382; called by muse, mutect2, varscan2
- ATP6V0A4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1393351118; called by muse, mutect2, varscan2
- ATP8A2 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.987); catalogued as rs781564289; called by muse, mutect2, varscan2
- CDH23 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773449705; called by muse, mutect2, varscan2
- CSMD1 | c.9689G>T p.S3230I (on ENST00000520002; = p.S3229I on NM_033225.6) | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs781377775; called by muse, mutect2, varscan2
- GRK2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57752716; called by muse, mutect2, varscan2
- IMPG1 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV64054078, COSV64057361; called by muse, mutect2
- KBTBD7 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267096; called by muse, mutect2, varscan2
- LPA | c.4850A>G p.Y1617C | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752997018; called by muse, mutect2, varscan2
- OR2C3 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100825565; called by muse, mutect2, varscan2
- OR51F2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100438024; called by muse, mutect2
- OR52D1 | c.913A>T p.S305C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1324685098; called by muse, mutect2, varscan2
- PCCB | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52444264; called by muse, mutect2, varscan2
- PCDHA2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV65371830; called by muse, mutect2, varscan2
- PRMT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV54919685; called by muse, mutect2, varscan2
- SLC2A13 | c.609T>A p.N203K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55117514; called by muse, mutect2, varscan2
- USF2 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99723504; called by muse, mutect2, varscan2
- USH2A | c.9413del p.G3138Afs*22 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | catalogued as CM155006, COSV56438014; called by mutect2, pindel, varscan2
- ZNF835 | c.429C>G p.C143W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101606358; called by muse, mutect2, varscan2
- ANOS1 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- BAZ2A | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CGN | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- CNGA2 | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNKSR1 | c.96_109del p.L33Pfs*55 | Frame Shift Del (DEL) | VAF 21/187 reads (11%) | called by mutect2, pindel
- CYB561D1 | c.204_209del p.E69_A70del | In Frame Del (DEL) | VAF 17/120 reads (14%) | called by mutect2, pindel, varscan2
- ERLEC1 | c.703_747del p.E235_Y249del | In Frame Del (DEL) | VAF 13/123 reads (11%) | called by mutect2, pindel
- F8 | c.5800A>T p.N1934Y | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FAM83E | c.173_176del p.F58Sfs*40 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- GPR3 | c.525G>C p.W175C | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LILRB1 | c.173A>G p.Q58R (on ENST00000427581; = p.Q22R on NM_006669.6) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- LRRK2 | c.5005G>C p.V1669L | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2
- MAGEC1 | c.3323A>T p.K1108I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MAGEC1 | c.3324A>T p.K1108N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MTMR14 | c.568C>A p.H190N | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- OGT | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- OR10C1 | c.544A>T p.I182F (on ENST00000622521; = p.I180F on NM_013941.3) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR4X2 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PCMTD1 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PDCD1LG2 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); called by muse, mutect2
- PPP6R3 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- QSER1 | c.3184G>A p.E1062K (on ENST00000399302; = p.E1191K on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB11FIP2 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RINL | c.386G>C p.R129T (on ENST00000591812 / NM_001195833.2; = p.R15T on NM_198445.4) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC44A2 | c.1646G>C p.W549S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SNX9 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SPEN | c.1982G>T p.W661L | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SPRING1 | c.86A>C p.Y29S | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- SPTLC1 | c.984+2T>A p.X328_splice | Splice Site (SNP) | VAF 14/271 reads (5%) | called by muse, mutect2
- STXBP6 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2
- TP53 | c.241dup p.T81Nfs*68 | Frame Shift Ins (INS) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- TRIM17 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZBED9 | c.2349A>T p.K783N | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNNM1 | c.717C>T p.F239= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CPA5 | c.141C>T p.A47= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1562946760; called by muse, mutect2
- DTHD1 | c.1615C>T p.L539= (on ENST00000456874; = p.L374= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/156 reads (13%) | catalogued as rs1331685734; called by muse, mutect2, varscan2
- FLNC | c.6609C>T p.R2203= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs374101315; called by muse, mutect2, varscan2
- FTHL17 | c.459G>T p.V153= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, varscan2
- HSPA12A | c.318T>C p.T106= | Silent (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4620G>A p.T1540= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs916290152; called by muse, mutect2, varscan2
- KRTAP13-4 | c.327C>T p.S109= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1473843642; called by muse, mutect2, varscan2
- MAN2B2 | c.267G>C p.S89= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs375473664; called by mutect2, varscan2
- PKD1L1 | c.5637C>T p.H1879= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as rs138494625; called by muse, mutect2, varscan2
- SLC8A2 | c.846G>T p.L282= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- SNX32 | c.99A>C p.A33= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs369776314; called by muse, mutect2, varscan2
- STXBP6 | c.204T>C p.F68= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as rs1374027734; called by muse, mutect2
- TMEM45B | c.591A>G p.P197= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs1157364815; called by muse, mutect2, varscan2
- TOE1 | c.828C>T p.S276= | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2, varscan2
- TRIM72 | c.1269C>A p.V423= | Silent (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- UMODL1 | c.1443C>A p.S481= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- CFAP74 | c.4653+271T>G | Intron (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- FSHR | c.374+2603A>C | Intron (SNP) | VAF 26/186 reads (14%) | called by muse, varscan2
- PMM2 | c.347+29A>C | Intron (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- SEC63 | c.1935+17C>T | Intron (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*468G>A | 3'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
